CPTAC case C3N-02282 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/438e5345-b54e-49e4-bad9-f1bc38839463

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 63.6 years (23,227 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,831 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,831 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 440 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 737 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 813 days (2.2 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,028 days (2.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,392 days (3.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,831 days (5.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 1.

Other clinical attributes
- Weight: 97 kg; Height: 173 cm; BMI: 32.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02282-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 582 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02282-25: Section location: Left Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3N-02282-10: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 267 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02282-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
